Somatic mutation profile of tumor specimen TCGA-FS-A1ZF-06A (aliquot TCGA-FS-A1ZF-06A-12D-A197-08) from TCGA case TCGA-FS-A1ZF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.4 years (28,624 days).
Specimen TCGA-FS-A1ZF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6699c82-1789-4999-abb7-770dbad3ffaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZF-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZF-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f159e4d-95d6-4e99-befe-0ea5cbfe50e7

The open-access MAF lists 243 somatic variants for this specimen: 156 protein-altering or splice-affecting, 82 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 82, Nonsense Mutation 9, Splice Site 4, RNA 3, 5'UTR 1, Frame Shift Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.92T>A p.L31* | Nonsense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as COSV60627896; called by muse, mutect2, varscan2
- ABCC11 | c.3692C>T p.T1231I | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1397053132, COSV62324428; called by muse, mutect2, varscan2
- ABL1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV59336093; called by muse, mutect2, varscan2
- ACTL6B | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50516365; called by mutect2, varscan2
- ADAMDEC1 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56476070; called by muse, mutect2, varscan2
- ADGRL3 | c.2680C>T p.R894C (on ENST00000506720 / NM_001322402.2; = p.R826C on NM_015236.6) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs370521883; called by muse, mutect2, varscan2
- AGXT2 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs762356643, COSV51485753; called by muse, mutect2, varscan2
- AIPL1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs549595673, COSV51506031; called by muse, mutect2, varscan2
- AL592490.1 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs772817874, COSV69426960; called by muse, mutect2, varscan2
- ALPK2 | c.5747G>A p.G1916D | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64494612; called by muse, mutect2, varscan2
- AP4E1 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55918445; called by muse, mutect2, varscan2
- APOB | c.11107C>T p.R3703C | Missense Mutation (SNP) | VAF 276/612 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs777896608, COSV51932917, COSV99266703; called by muse, mutect2, varscan2
- APOB | c.4202C>T p.S1401F | Missense Mutation (SNP) | VAF 189/464 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51936527; called by muse, mutect2, varscan2
- ARPP21 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV99492914; called by muse, mutect2, varscan2
- ASXL3 | c.2649A>C p.L883F | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.109); catalogued as COSV52472182; called by muse, mutect2, varscan2
- BCAN | c.2325C>A p.D775E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61257983; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2, varscan2
- BPTF | c.9032C>T p.S3011F | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58841407; called by muse, mutect2, varscan2
- CACNA1A | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV64204173; called by muse, mutect2, varscan2
- CACNA1I | c.2638C>T p.Q880* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100361156, COSV60813429; called by muse, mutect2, varscan2
- CACNA2D3 | c.1772T>A p.V591E | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55558265; called by muse, mutect2, varscan2
- CAMSAP2 | c.682C>T p.R228C (on ENST00000236925 / NM_001297707.2; = p.R217C on NM_203459.3) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1451569666, COSV52673749; called by muse, mutect2, varscan2
- CCDC88C | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1160750166, COSV101106045; called by muse, mutect2, varscan2
- CCL27 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 92/122 reads (75%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as COSV52405301; called by muse, mutect2, varscan2
- CFHR2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs767481045, COSV66381620; called by muse, mutect2, varscan2
- CHD6 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 136/380 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV58559467; called by muse, mutect2, varscan2
- CHERP | c.2417C>A p.S806Y | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV52225885; called by muse, mutect2, varscan2
- CLASP2 | c.2608A>G p.M870V | Missense Mutation (SNP) | VAF 170/372 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs755029277, COSV56287325; called by muse, mutect2, varscan2
- CNTN1 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs148624625, COSV61641574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COX11 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.018); catalogued as COSV54803351; called by muse, mutect2, varscan2
- CRYBG1 | c.5765G>A p.G1922E | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64811873; called by muse, mutect2, varscan2
- CSMD1 | c.4180G>A p.D1394N (on ENST00000520002; = p.D1393N on NM_033225.6) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779702652, COSV59321276, COSV99045826; called by muse, mutect2, varscan2
- CTSE | c.1042-1G>A p.X348_splice (on ENST00000360218; = p.X343_splice on NM_001910.4) | Splice Site (SNP) | VAF 83/349 reads (24%) | catalogued as COSV63061271; called by muse, mutect2, varscan2
- CYP3A5 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56121447; called by muse, mutect2, varscan2
- DAZL | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51713523, COSV99167547; called by muse, mutect2, varscan2
- DLGAP4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV59416609, COSV59416935; called by muse, mutect2, varscan2
- DNAH5 | c.10666C>T p.P3556S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54221831; called by muse, mutect2, varscan2
- DSCAM | c.2345T>A p.L782H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV68025375, COSV68031117; called by muse, mutect2, varscan2
- DYNC1H1 | c.12448C>T p.P4150S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV64139234; called by muse, mutect2, varscan2
- ECHS1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV63907063; called by muse, mutect2, varscan2
- EEF1A1 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs759800146, COSV58550240; called by mutect2, varscan2
- EMG1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV99781266; called by muse, mutect2, varscan2
- ENPP6 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV99699072; called by muse, mutect2, varscan2
- ENTPD3 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV57195403; called by muse, mutect2, varscan2
- EPHA1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV51973150; called by muse, mutect2, varscan2
- ERC2 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV55640574; called by muse, mutect2, varscan2
- ERP27 | c.231C>A p.S77R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.693); catalogued as COSV56764026; called by muse, mutect2
- ETV3L | c.521T>C p.M174T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV71901155; called by muse, mutect2, varscan2
- FAT3 | c.8069C>T p.S2690F | Missense Mutation (SNP) | VAF 263/351 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53114286; called by muse, mutect2, varscan2
- FAT4 | c.14522C>T p.S4841F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58696533; called by muse, mutect2, varscan2
- FLG | c.7502C>T p.S2501F | Missense Mutation (SNP) | VAF 334/560 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV64244638; called by muse, mutect2, varscan2
- FLG2 | c.6434G>A p.G2145E | Missense Mutation (SNP) | VAF 314/537 reads (58%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.448); catalogued as COSV66170571; called by muse, mutect2, varscan2
- FLG2 | c.6185G>A p.G2062E | Missense Mutation (SNP) | VAF 353/587 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs754771681, COSV66167772, COSV66168074; called by muse, mutect2, varscan2
- FOLR1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.87); catalogued as rs1565365932, COSV56616581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYB2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV58586907; called by muse, mutect2, varscan2
- GABRB1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54972822; called by muse, mutect2, varscan2
- GNL1 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64921239; called by muse, mutect2, varscan2
- GPR143 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV66632776; called by muse, mutect2, varscan2
- GRIN2A | c.3442C>T p.P1148S | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.798); catalogued as COSV58028910, COSV58031121; called by muse, mutect2, varscan2
- HTT | c.3671C>T p.S1224F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV61865332; called by muse, mutect2, varscan2
- IGSF5 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV66030838; called by muse, mutect2, varscan2
- IMPG1 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV64059671; called by muse, mutect2, varscan2
- INSRR | c.2624G>A p.G875E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748525262, COSV63875278; called by muse, mutect2, varscan2
- KDM2B | c.3383C>T p.S1128F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV65642504; called by muse, mutect2, varscan2
- KIF16B | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV61709508; called by muse, mutect2, varscan2
- KLK11 | c.145G>A p.G49R (on ENST00000594768 / NM_144947.3; = p.G17R on NM_006853.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1568572632, COSV51577984, COSV99142046; called by muse, mutect2, varscan2
- KRT4 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99543149; called by muse, mutect2, varscan2
- KRT4 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV53407175, COSV99543150; called by muse, mutect2, varscan2
- LAMA2 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs558018507, COSV70351696; called by muse, mutect2, varscan2
- LHFPL5 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219567054, COSV64178274; called by muse, mutect2, varscan2
- LPCAT1 | c.1263C>G p.I421M | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV52039434; called by muse, mutect2, varscan2
- LRRIQ4 | c.1461T>G p.C487W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100540001, COSV61619654; called by muse, varscan2
- LTBP3 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99534473; called by muse, mutect2, varscan2
- MED13L | c.3257C>T p.P1086L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765954704, COSV99929827; called by muse, mutect2, varscan2
- MEFV | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV54824535; called by muse, mutect2, varscan2
- METTL7B | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV57697705; called by muse, mutect2, varscan2
- MON2 | c.4257T>A p.D1419E | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV54810330; called by muse, mutect2, varscan2
- MUC16 | c.17551C>T p.P5851S | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs267605800, COSV67460962; called by muse, mutect2, varscan2
- MUC5AC | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.02); catalogued as COSV62254653; called by muse, mutect2
- MUC5B | c.4505C>T p.T1502I | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV71594019; called by muse, mutect2, varscan2
- MYH4 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV55122072; called by muse, mutect2, varscan2
- NCDN | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV61936231; called by muse, mutect2, varscan2
- NCOR1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | catalogued as COSV51973215, COSV51984363; called by muse, mutect2, varscan2
- NDST3 | c.701T>A p.I234K | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV56623628; called by muse, mutect2, varscan2
- NDUFA13 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99389216; called by muse, mutect2, varscan2
- NR1H2 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53801386; called by muse, mutect2, varscan2
- NUCKS1 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 72/129 reads (56%) | catalogued as COSV63347869; called by muse, mutect2, varscan2
- NUGGC | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV58432905; called by muse, mutect2, varscan2
- NXF5 | n.601-1G>A | Splice Site (SNP) | VAF 48/66 reads (73%) | catalogued as COSV53792110; called by muse, mutect2, varscan2
- OR10H5 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58278694; called by muse, mutect2, varscan2
- OR11H1 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 113/281 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53271601; called by muse, mutect2, varscan2
- OR2L3 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs202209437, COSV63455676; called by muse, mutect2, varscan2
- OR6B1 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV68770330; called by muse, mutect2, varscan2
- OTOF | c.2869A>T p.K957* (on ENST00000272371 / NM_194248.3; = p.K210* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as rs1403187187, COSV55509620; called by muse, mutect2, varscan2
- PASK | c.2800C>T p.H934Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs1159016713, COSV52156003; called by muse, mutect2, varscan2
- PCLO | c.8095C>T p.P2699S | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs551639501, COSV100437801, COSV61624916; called by muse, mutect2, varscan2
- PDGFRA | c.1984G>A p.G662R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57270730; called by muse, mutect2, varscan2
- PEAR1 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1315490606, COSV52774382; called by muse, mutect2, varscan2
- PLCZ1 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1418319077, COSV56855912; called by muse, mutect2, varscan2
- PLXND1 | c.3787C>G p.L1263V | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60716160; called by muse, mutect2, varscan2
- PNN | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 165/453 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777981655, COSV53767384; called by muse, mutect2, varscan2
- PNPLA5 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); catalogued as COSV99336740; called by muse, mutect2, varscan2
- POLR2C | c.528G>T p.W176C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54673633; called by muse, varscan2
- PPL | c.3922G>A p.V1308M | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99063800; called by muse, mutect2, varscan2
- PRDM1 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs960785645, COSV100958953; called by muse, mutect2, varscan2
- PRKCG | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 125/322 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54724789; called by muse, mutect2, varscan2
- PRR16 | c.326A>C p.H109P (on ENST00000407149 / NM_001300783.2; = p.H86P on NM_016644.2) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.347); catalogued as COSV65399848, COSV65401995; called by muse, mutect2, varscan2
- PRRT1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52999005; called by muse, mutect2, varscan2
- PTPN9 | c.690T>A p.C230* | Nonsense Mutation (SNP) | VAF 35/93 reads (38%) | catalogued as COSV60724732; called by muse, mutect2, varscan2
- RNF165 | c.377+2T>G p.X126_splice | Splice Site (SNP) | VAF 18/38 reads (47%) | catalogued as COSV53975840; called by muse, mutect2, varscan2
- ROS1 | c.6541G>A p.E2181K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as COSV63858100; called by muse, mutect2
- RRM2B | c.838A>G p.I280V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs754185209, COSV52567673; called by muse, mutect2, varscan2
- RXRG | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717788; called by muse, mutect2, varscan2
- SCN10A | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV71862132; called by muse, mutect2, varscan2
- SENP7 | c.3046C>T p.H1016Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100053658; called by muse, mutect2, varscan2
- SIGLEC11 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV70222072; called by muse, mutect2, varscan2
- SLC1A3 | c.877A>T p.I293F | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54318293; called by muse, mutect2, varscan2
- SLC22A25 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV60597363; called by muse, mutect2, varscan2
- SLC26A9 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 93/398 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs753275770, COSV61604182; called by muse, mutect2, varscan2
- SLC28A1 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as COSV54476492; called by muse, mutect2, varscan2
- SLC6A13 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs778879939, COSV58258312; called by muse, mutect2, varscan2
- SLC8A3 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63519505; called by muse, mutect2, varscan2
- SLC9C1 | c.713T>C p.F238S | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59890150; called by muse, mutect2, varscan2
- SPATS2L | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as COSV62350313; called by muse, mutect2
- STK10 | c.1147T>G p.S383A | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV51576352; called by muse, mutect2, varscan2
- SYCP1 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); catalogued as rs771129520, COSV65695325; called by muse, mutect2, varscan2
- TICRR | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV51543903; called by muse, mutect2, varscan2
- TLL1 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV50303987; called by muse, mutect2, varscan2
- TMTC2 | c.2078A>T p.K693M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.888); catalogued as COSV58275574; called by muse, mutect2, varscan2
- TNIK | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs541715266, COSV52687955; called by muse, mutect2, varscan2
- TOX2 | c.441C>T p.I147= (on ENST00000358131 / NM_001098798.2; = p.I96= on NM_032883.3) | Splice Region (SNP) | VAF 24/55 reads (44%) | catalogued as COSV57890428; called by muse, mutect2, varscan2
- TRIM42 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs200221279, COSV53880710; called by muse, mutect2, varscan2
- TRIM60 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV100594143, COSV61971051; called by muse, mutect2, varscan2
- TRIO | c.5872G>A p.E1958K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV60088091; called by muse, mutect2, varscan2
- TRPM6 | c.3881G>A p.R1294K | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV62510335, COSV62516046; called by muse, mutect2, varscan2
- TTN | c.34885C>T p.P11629S (on ENST00000591111; = p.P10702S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | PolyPhen benign (0.234); catalogued as COSV60184559, COSV60195363; called by muse, mutect2, varscan2
- TULP2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55479048; called by muse, mutect2, varscan2
- USP10 | c.337A>T p.I113F | Missense Mutation (SNP) | VAF 56/71 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV54750740; called by muse, mutect2, varscan2
- VGLL4 | c.64+1G>T p.X22_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56080389, COSV99810201; called by muse, varscan2
- WASF1 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55620336; called by muse, mutect2, varscan2
- WDR25 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs200027763; called by muse, mutect2, varscan2
- WFS1 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 269/621 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs71524358; called by muse, mutect2, varscan2
- WNT7A | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 125/276 reads (45%) | catalogued as rs267599620, COSV53197800; called by muse, mutect2, varscan2
- WRAP53 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as rs376125064; called by muse, mutect2, varscan2
- ZC3H7B | c.689T>A p.F230Y | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as COSV60960690; called by muse, mutect2, varscan2
- ZFAT | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 74/161 reads (46%) | catalogued as COSV64741947; called by muse, mutect2, varscan2
- ZFHX3 | c.5345T>A p.M1782K | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV51726093; called by muse, mutect2, varscan2
- ZNF440 | c.612T>A p.F204L | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.93); catalogued as COSV58371748; called by muse, mutect2
- ZNF648 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV60571796; called by muse, mutect2, varscan2
- ZNF711 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs866850423, COSV52156660, COSV99341213; called by muse, mutect2, varscan2
- ZNF831 | c.3884G>A p.G1295E | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as COSV64042624; called by muse, mutect2, varscan2
- ZNF831 | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as rs773192622, COSV64042630; called by muse, mutect2, varscan2
- ZSCAN1 | c.642G>A p.W214* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as COSV56606351; called by muse, mutect2, varscan2
- TBC1D4 | c.2976del p.F992Lfs*4 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | called by mutect2, pindel, varscan2
- APBA2 | c.918C>T p.T306= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV68793041; called by muse, mutect2, varscan2
- ATP8A1 | c.2616C>T p.I872= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs755858752, COSV52540383; called by muse, mutect2, varscan2
- CASP4 | c.48C>T p.S16= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as COSV67744302; called by muse, mutect2, varscan2
- CCDC88C | c.2355G>A p.L785= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs759643247, COSV101106046; called by muse, mutect2, varscan2
- CD163 | c.276G>A p.L92= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as COSV63134938; called by muse, mutect2, varscan2
- CDH22 | c.465C>T p.I155= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV64838434; called by muse, mutect2, varscan2
- CENPF | c.6414C>T p.I2138= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs755070987, COSV65276595; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLSTN2 | c.1098C>T p.V366= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs764918816, COSV101515384, COSV71722842; ClinVar: likely benign; called by muse, mutect2
- CNBD2 | c.1362G>A p.K454= (on ENST00000373973 / NM_001365709.1; = p.K450= on NM_080834.4) | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV62587389; called by muse, mutect2, varscan2
- DCC | c.4077G>A p.P1359= | Silent (SNP) | VAF 64/167 reads (38%) | catalogued as rs571287631, COSV71432561; called by muse, mutect2, varscan2
- DDX60 | c.3777G>A p.R1259= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs778810404, COSV67097803; called by muse, mutect2, varscan2
- DMBT1 | c.3009G>A p.Q1003= (on ENST00000338354 / NM_001377530.1; = p.Q504= on NM_004406.3) | Silent (SNP) | VAF 207/280 reads (74%) | catalogued as rs766504761, COSV57551485; called by muse, mutect2, varscan2
- DNAH17 | c.3345G>A p.K1115= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV67758183; called by muse, mutect2, varscan2
- DNAH5 | c.13704G>A p.R4568= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV54238466; called by muse, mutect2, varscan2
- DNAH9 | c.8031C>T p.F2677= | Silent (SNP) | VAF 75/159 reads (47%) | catalogued as rs1479330984, COSV52360454; called by muse, mutect2, varscan2
- EMG1 | c.12C>T p.P4= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs781917483, COSV99781268; called by muse, mutect2, varscan2
- EMSY | c.2856G>A p.Q952= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV58263233, COSV58267045; called by muse, mutect2, varscan2
- ENPP6 | c.837C>T p.A279= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV99699071; called by muse, mutect2, varscan2
- EPB41L1 | c.1881C>T p.D627= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV52440606; called by muse, mutect2, varscan2
- ERI3 | c.316T>C p.L106= | Silent (SNP) | VAF 102/230 reads (44%) | catalogued as COSV64831506; called by muse, mutect2, varscan2
- FAM102A | c.972C>T p.I324= (on ENST00000373095 / NM_001035254.3; = p.I182= on NM_203305.2) | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs1247734848, COSV55948461; called by muse, mutect2, varscan2
- FAM9C | c.462G>A p.K154= | Silent (SNP) | VAF 31/40 reads (78%) | catalogued as COSV100452889, COSV61775758; called by muse, mutect2, varscan2
- FCRL4 | c.951G>A p.G317= | Silent (SNP) | VAF 78/142 reads (55%) | catalogued as rs376872127; called by muse, mutect2, varscan2
- FES | c.1305C>T p.F435= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as rs1213823064, COSV60998379; called by muse, mutect2, varscan2
- FXR2 | c.577C>T p.L193= | Silent (SNP) | VAF 102/246 reads (41%) | catalogued as COSV51517738, COSV51519290; called by muse, mutect2, varscan2
- GOLGA4 | c.1020G>A p.E340= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1351822536, COSV62711451; called by muse, mutect2, varscan2
- GOLGB1 | c.2520G>A p.L840= | Silent (SNP) | VAF 69/162 reads (43%) | catalogued as COSV61467965; called by muse, mutect2, varscan2
- GUCY2F | c.1683C>T p.S561= | Silent (SNP) | VAF 96/122 reads (79%) | catalogued as COSV54305371; called by muse, mutect2, varscan2
- HMCN1 | c.3180C>T p.A1060= | Silent (SNP) | VAF 53/79 reads (67%) | catalogued as COSV54917493; called by muse, mutect2, varscan2
- HROB | c.651C>T p.I217= | Silent (SNP) | VAF 56/73 reads (77%) | catalogued as COSV55370193; called by muse, mutect2, varscan2
- IGLV7-43 | c.252A>C p.S84= | Silent (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- IQCH | c.1530C>T p.I510= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV60056247; called by muse, mutect2, varscan2
- JAKMIP2 | c.1512C>T p.D504= | Silent (SNP) | VAF 217/255 reads (85%) | catalogued as rs759282429, COSV54609320; called by muse, mutect2, varscan2
- KCNT2 | c.195C>T p.F65= | Silent (SNP) | VAF 125/210 reads (60%) | catalogued as COSV54071828; called by muse, mutect2, varscan2
- LPCAT1 | c.1539C>T p.F513= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV52036784; called by muse, mutect2, varscan2
- LRP2 | c.11370A>G p.E3790= | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as rs917219419, COSV55562157; called by muse, mutect2, varscan2
- LTBP3 | c.2643G>A p.G881= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV99534474; called by muse, mutect2, varscan2
- MAGEA12 | c.429C>T p.F143= | Silent (SNP) | VAF 87/98 reads (89%) | catalogued as COSV63294853; called by muse, mutect2, varscan2
- MAPKBP1 | c.2244C>T p.R748= (on ENST00000456763 / NM_001128608.2; = p.R742= on NM_014994.3) | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as COSV52964350; called by muse, mutect2, varscan2
- MARF1 | c.1689C>T p.R563= | Silent (SNP) | VAF 75/148 reads (51%) | catalogued as rs200110309, COSV60025917; called by muse, mutect2, varscan2
- MED13L | c.3258C>T p.P1086= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs1477751856, COSV99929826; called by muse, mutect2, varscan2
- MTUS2 | c.1650A>G p.T550= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV70918323; called by muse, mutect2, varscan2
- MUC16 | c.23523G>A p.G7841= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV67478931; called by muse, mutect2, varscan2
- MYBPC2 | c.1128G>A p.V376= | Silent (SNP) | VAF 74/164 reads (45%) | catalogued as COSV63097556; called by muse, mutect2, varscan2
- MYT1L | c.2895G>A p.G965= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as COSV67703672; called by muse, mutect2, varscan2
- NDN | c.864G>A p.Q288= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV59360517; called by muse, mutect2, varscan2
- NLRP11 | c.1014C>T p.V338= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs1455149403, COSV64088202; called by muse, mutect2, varscan2
- OR4K1 | c.669C>T p.I223= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs141997601, COSV53459749; called by muse, mutect2, varscan2
- OR6B2 | c.282C>T p.F94= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as rs750021015, COSV53153142; called by muse, mutect2, varscan2
- PDCL | c.549C>A p.I183= | Silent (SNP) | VAF 42/49 reads (86%) | catalogued as COSV52343102, COSV52343532; called by muse, mutect2, varscan2
- PNPLA5 | c.972G>A p.R324= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV99336742; called by muse, mutect2, varscan2
- PPL | c.3921G>A p.E1307= | Silent (SNP) | VAF 89/231 reads (39%) | catalogued as COSV99278487; called by muse, mutect2, varscan2
- PRSS38 | c.405G>A p.V135= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV64540980; called by muse, mutect2, varscan2
- PTPN1 | c.675C>T p.F225= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV65408702; called by muse, mutect2, varscan2
- PTPRC | c.2214G>A p.R738= | Silent (SNP) | VAF 455/762 reads (60%) | catalogued as COSV61415879; called by muse, mutect2, varscan2
- RNLS | c.898C>T p.L300= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as COSV64265008; called by muse, mutect2, varscan2
- RPS6KA3 | c.528A>G p.E176= | Silent (SNP) | VAF 32/36 reads (89%) | catalogued as COSV65388570; called by muse, mutect2, varscan2
- RXRG | c.1284C>T p.S428= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as COSV100717787; called by muse, mutect2, varscan2
- SAMSN1 | c.183T>C p.N61= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV53474175; called by muse, mutect2, varscan2
- SCN3B | c.492C>T p.I164= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as COSV54800237; called by muse, mutect2, varscan2
- SERPINB4 | c.72G>A p.E24= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs868764843, COSV61985538; called by muse, mutect2, varscan2
- SGCZ | c.588G>A p.P196= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs775208052, COSV66016854; called by muse, mutect2, varscan2
- SLC28A1 | c.1077C>T p.S359= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV99723403; called by muse, mutect2, varscan2
- SOX10 | c.1188C>T p.S396= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV62806963; called by muse, mutect2, varscan2
- TBC1D4 | c.2979C>T p.N993= | Silent (SNP) | VAF 30/62 reads (48%) | called by mutect2, varscan2
- TBX3 | c.996G>A p.E332= (on ENST00000257566 / NM_016569.4; = p.E312= on NM_005996.4) | Silent (SNP) | VAF 66/132 reads (50%) | catalogued as COSV57473532; called by muse, varscan2
- TENM3 | c.3777G>A p.G1259= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as rs767980114, COSV69313516; called by muse, mutect2, varscan2
- TIGD3 | c.1287C>T p.P429= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV52890361; called by muse, mutect2, varscan2
- TLN2 | c.1689C>T p.L563= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV60892049; called by muse, mutect2, varscan2
- TMPRSS9 | c.378C>T p.H126= (on ENST00000648592; = p.H92= on NM_182973.2) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV60229345; called by muse, mutect2, varscan2
- TNNT2 | c.774C>T p.F258= (on ENST00000236918; = p.F255= on NM_000364.4) | Silent (SNP) | VAF 161/454 reads (35%) | catalogued as rs397516481, COSV52663865; ClinVar: likely benign; called by muse, varscan2
- TRIM46 | c.1119A>T p.T373= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV55279590; called by muse, mutect2, varscan2
- TTN | c.1704A>G p.V568= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as rs1195717971, COSV60184570; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR4 | c.7233A>G p.P2411= | Silent (SNP) | VAF 75/190 reads (39%) | catalogued as COSV64394035; called by muse, mutect2, varscan2
- UGGT1 | c.3165G>A p.K1055= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs1295640520, COSV52138464; called by muse, mutect2, varscan2
- WDR25 | c.1155C>T p.L385= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100092136; called by muse, mutect2
- WNT7A | c.564C>T p.G188= | Silent (SNP) | VAF 123/273 reads (45%) | catalogued as COSV99541612; called by muse, mutect2, varscan2
- XPO5 | c.1785G>C p.R595= | Silent (SNP) | VAF 65/128 reads (51%) | catalogued as COSV54832411; called by muse, mutect2, varscan2
- YLPM1 | c.5787C>T p.I1929= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV53116034; called by muse, mutect2, varscan2
- ZNF711 | c.387C>T p.F129= | Silent (SNP) | VAF 66/87 reads (76%) | catalogued as rs867259256, COSV52156636; called by muse, mutect2, varscan2
- ZNF775 | c.192G>A p.G64= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV61613908; called by muse, mutect2, varscan2
- ZP2 | c.1911C>T p.S637= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs748977170, COSV54813682, COSV54815158; called by muse, mutect2, varscan2
- AL133467.6 | n.85C>T | RNA (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- MIR543 | n.78C>T | RNA (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- SPATA8 | n.790G>A | RNA (SNP) | VAF 24/78 reads (31%) | catalogued as rs865808886, COSV60705198; called by muse, mutect2, varscan2
- TPM4 | chr19:16076083 A>C | 5'Flank (SNP) | VAF 7/16 reads (44%) | catalogued as COSV56289377; called by muse, mutect2, varscan2
- USP5 | c.-1C>T | 5'UTR (SNP) | VAF 11/29 reads (38%) | catalogued as rs781983695, COSV99977070; called by muse, mutect2, varscan2
